Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A748, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A748-01A (Primary Tumor).

Patient: XXX

Age:

Gender: F

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion)

Date of admission:

CSCE ICD-O-3
Adenocarcinoma, diffuse type 8145/3
path Adenocarcinoma, mucocellular 8490/3
Site CSCE Gastric fundus C16.1
path Stomach NOS C16.9

Material:

1) Material: stomach, stomach with the tumour. Method of collection: Total organ resection

JA 5/25/13

Histopathological diagnosis:

Examination performed on:

Mucocellular adenocarcinoma of the Stomach (diffuse).

Metastases in 12/16 adjacent lymph nodes.

G3, pT4a, pN3a, pMx.

Spleen and omentum free of cancer. (8490/3 T-63000)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Stomach, after being incised along the greater curvature sized 23 x 17 cm with the omentum sized 25 x 8cm. Additionally, the pancreas sized 14 x 8 x 5cm. The mucosa exhibiting an ulcerated tumour of 5.0 x 4 x 2cm. The lesion is located 6.0cm away from the proximal incision line, and 9cm from the distal one.

Microscopic description:

Gastric mucocellular adenocarcinoma (G3 acc. to Lauren, diffuse type). Tumour infiltrating the serous membrane (pT4a) Metastases to 3/3 pericardial lymph nodes, 5/5 lesser curvature lymph nodes, 1/2 greater curvature lymph nodes, 3/6 peripyloric lymph nodes - total: 12/16 lymph nodes involved. Spleen free of cancer. Two lymph of the hilum lienale nodes free of cancer.

Assistant:

Pathologist:

Edited by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Criteria -	Yes	No
HPA Discrepancy		✓

Source: NCI Genomic Data Commons file 28d54e90-28ab-4412-8f19-4a066524c3f6 (TCGA-D7-A748.F38EE87F-1678-4E70-A003-9CDCFEC813D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).